Surgical pathology report (de-identified scan), TCGA case TCGA-76-6283, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-6283-01A (Primary Tumor).

[page 1 of 6]
[REDACTED]

Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED] TCGA - 76 - 6283

FINAL DIAGNOSIS:

1. Left frontal tumor: GLIOBLASTOMA, WHO GRADE IV.
2. Left frontal tumor: GLIOBLASTOMA, WHO GRADE IV. SEE MICROSCOPIC DESCRIPTION.

[REDACTED]

Report Electronically Signed on [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor is composed of markedly pleomorphic cells. Numerous mitotic figures are identified in the tumor and the Ki67 proliferation index is approximately 80%. Foci of tumor necrosis including pseudopalisading necrosis are present. Large portions of the tumor are composed of tumor cells that contain irregular nuclei including very large nuclei. Many of the tumor cells display features of a giant cell glioblastoma. Scattered markedly pleomorphic tumor cells show positive immunohistochemical staining for GFAP. Small foci of more gemistocytic appearing tumor cells are present on slide 1A and 2B.

A separate immunohistochemical report will be issued.

Frozen Section Diagnosis:

1. Left frontal tumor: Malignant high-grade glioma

Clinical History and Diagnosis:

[page 2 of 6]
Glioma

Source of Specimen:

- 1: Left frontal tumor
- 2: Left frontal tumor

Gross Description:

1. Left frontal tumor: Received for frozen section in a specimen container labeled with the patient's name and "#1 left frontal tumor" are 4 fragments of tan-red soft partially gelatinous tissue ranging from 0.4 to 1.5 cm in greatest dimension. Approximately half of the specimen is frozen for frozen section diagnosis and the entire specimen is submitted in two cassettes for permanent sections.
2. Left frontal tumor: Received in formalin in a container labeled with the patient's name and "#2 left frontal tumor", multiple fragments of soft, tan-white tissue measuring 3.2 x 1.5 x 1.0 cm in aggregate. The specimen is submitted entirely in 3 cassettes.

Histology Laboratory
H&E

Part 2: Left frontal tumor
UNSTAINED
UNSTAINED
UNSTAINED
UNSTAINED

[page 3 of 6]
[REDACTED]

Patient: [REDACTED]

IMMUNOPATHOLOGY REPORT

EVALUATION:

GFAP: POSITIVE STAINING IN TUMOR CELLS.

KI67: POSITIVE STAINING IN APPROXIMATELY 80% OF TUMOR CELL NUCLEI.

P53: POSITIVE STAINING IN GREATER THAN 50% OF TUMOR CELL NUCLEI.

CHROMOGRANIN: NEGATIVE IN TUMOR CELLS.

SYNAPTOPHYSIN: NEGATIVE IN TUMOR CELLS.

NEUROFILAMENT: NEGATIVE IN TUMOR CELLS. POSITIVE STAINING OF AXONS IN
BRAIN TISSUE INFILTRATED BY TUMOR.

NEU-n: FOCAL POSITIVE STAINING OF TUMOR CELL NUCLEI IN PORTIONS OF THE
TUMOR (Slide 2C).

Comment:

The immunohistochemical stains support the diagnosis of Glioblastoma.
See corresponding surgical pathology report [REDACTED] The
identification of a single neuronal antigen is not sufficient for a
designation of Malignant glioneuronal tumor [REDACTED]
[REDACTED]

[REDACTED]
Report Electronically Signed on [REDACTED]

This diagnostic report has been personally interpreted by the signatory
of record.

[page 4 of 6]
[REDACTED]
Patient: [REDACTED]

MOLECULAR PATHOLOGY REPORT

EVALUATION:

ASSAY PERFORMED: del(1p)del(19q) BY FLUORESCENT IN-SITU HYBRIDIZATION (FISH)

RESULT: nuc ish 1p36(P73 x 1~5),1q24(ANGPTL1 x 1~5)[200],19p13(ZNF44 x 1~4),19q13(GLTSCR x 1~4)[200]

1p36/1q24

Number of Nuclei scored - 200

Ratio of 1p/1q 0.94

% cells with del 1p 16.5%

19q13/19p13

Number of Nuclei scored 200

Ratio of 19q/19p 0.92

% cells with del 19q 18.5%

INTERPRETATION: The results are within the normal range and suggest absence of deletions of 1p and 19q in this glioblastoma [REDACTED] del (1p) and del(19q) has been observed in glioma specimens, especially oligodendrogliomas. Clinical and pathologic correlation is recommended.

DESCRIPTION OF THE ASSAY: 1p and 19q FISH studies were performed on paraffin embedded tumor sections. Two hybridizations were performed: one with a 1p/1q probe/control pair and one with a 19q/19p probe/control pair. The 19q and 1p probes map to regions that are commonly deleted in gliomas. The nuclei are counterstained with DAPI and the cells examined by epi-fluorescence microscopy. The total number of counts for each probe is determined in 200 cells and the ratios of 1p/1q and 19q/19p are calculated.

Normal range: The normal ratio is approximately 1. Any ratio > 0.80 is

[page 5 of 6]
[REDACTED]

considered normal.

LIMITATIONS: Low levels of malignant cells in the specimen can result in a false negative result. As with all laboratory tests, sampling error and other factors may affect the outcome of the assay. Correlation of results with other clinical and laboratory data should be obtained.

COMMENT: This test was developed and its performance characteristics determined by the [REDACTED]

[REDACTED] It has not been cleared or approved by the U.S. Food and Drug Administration.

This test is not to be used as a diagnostic procedure without confirmation of the diagnosis by another medically established product or procedure.

[REDACTED]

Report Electronically Signed on [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Clinical History and Diagnosis:
Glioblastoma WHO Grade IV

Source of Specimen:
1: FISH-BRAIN

Gross Description:
[REDACTED]

Formalin fixed paraffin-embedded tissue
[REDACTED]

Histology Laboratory
H&E

Source: NCI Genomic Data Commons file e2362d25-ef29-4fdf-9f16-701184df7b55 (TCGA-76-6283.A4576D26-9F8E-472D-BE41-4B8632080C4A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).